Somatic mutation profile of tumor specimen 0E0UHW from CCDI case PBCVIN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0UHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cb407b7-9266-4824-a976-78f6085eb366.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0UI8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/781c408f-2153-4d90-bb01-c24592b0933d

The open-access MAF lists 111 somatic variants for this specimen: 78 protein-altering or splice-affecting, 13 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Intron 14, Silent 13, Nonsense Mutation 8, 3'UTR 4, Splice Site 2, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 229/581 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.1117C>A p.H373N | Missense Mutation (SNP) | VAF 166/485 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.845); catalogued as COSV53180226; called by muse, mutect2, varscan2
- ADAMTS7 | c.4915G>C p.D1639H | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66308136; called by muse, mutect2, varscan2
- ADGRE2 | c.2375G>T p.W792L | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs761872578, COSV59692009; called by muse, mutect2, varscan2
- AP1G2 | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 68/343 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99846362; called by muse, mutect2, varscan2
- ARHGAP9 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 26/642 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV62724376; called by muse, mutect2
- ARHGEF33 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 117/315 reads (37%) | catalogued as COSV67256737; called by muse, mutect2, varscan2
- FBN2 | c.6665C>T p.P2222L | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs747908706, COSV52520709; called by muse, mutect2, varscan2
- FLG | c.10350C>A p.Y3450* | Nonsense Mutation (SNP) | VAF 170/366 reads (46%) | catalogued as rs751349850, COSV64238542, COSV64239059; called by muse, mutect2, varscan2
- FLG | c.3961C>A p.H1321N | Missense Mutation (SNP) | VAF 71/481 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs776012559; called by muse, mutect2, varscan2
- GADL1 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 114/381 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1303669598; called by muse, mutect2, varscan2
- GIMAP1 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 100/696 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56187801; called by muse, mutect2, varscan2
- ITSN2 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 136/398 reads (34%) | catalogued as COSV61944286; called by muse, mutect2, varscan2
- MS4A14 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 171/545 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as rs768485346, COSV55735599, COSV55738032; called by muse, mutect2, varscan2
- NEDD9 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV101053375; called by muse, mutect2, varscan2
- OR5W2 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 195/672 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV60615604; called by muse, mutect2
- PALLD | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 153/480 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54989537; called by mutect2, varscan2
- SIAH1 | c.494T>G p.F165C | Missense Mutation (SNP) | VAF 210/522 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53522986; called by muse, mutect2, varscan2
- SKAP1 | c.179-1G>T p.X60_splice | Splice Site (SNP) | VAF 91/262 reads (35%) | catalogued as COSV100411881; called by muse, mutect2, varscan2
- SPTBN2 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 197/574 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59450070; called by muse, mutect2, varscan2
- TMEM151B | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315206129; called by muse, mutect2
- TMPRSS11E | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV59519085; called by muse, mutect2
- TOPAZ1 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 175/466 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs1460943298; called by muse, mutect2, varscan2
- TPO | c.2278G>T p.G760W | Missense Mutation (SNP) | VAF 157/426 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61107364; called by muse, mutect2, varscan2
- TRANK1 | c.1243G>T p.G415W | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV57160447; called by muse, mutect2
- ZNF114 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 111/417 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1225805360, COSV59945314; called by muse, mutect2, varscan2
- ZNF469 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 160/407 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1273508031; called by muse, mutect2, varscan2
- AHSG | c.13dup p.V5Gfs*24 | Frame Shift Ins (INS) | VAF 56/309 reads (18%) | called by mutect2, pindel, varscan2
- ALPK1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 186/692 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ANK3 | c.10805C>A p.P3602Q | Missense Mutation (SNP) | VAF 121/450 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATM | c.5763-1G>T p.X1921_splice | Splice Site (SNP) | VAF 55/86 reads (64%) | called by mutect2, varscan2
- ATP2B4 | c.3448G>T p.E1150* | Nonsense Mutation (SNP) | VAF 325/622 reads (52%) | called by muse, mutect2, varscan2
- AVIL | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 145/390 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRPF1 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 124/595 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- C1QTNF4 | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 174/623 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN7 | c.259T>A p.L87I | Missense Mutation (SNP) | VAF 181/482 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCDC141 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 167/480 reads (35%) | called by muse, mutect2, varscan2
- CLEC4F | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 192/580 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DOCK6 | c.2715C>A p.S905R | Missense Mutation (SNP) | VAF 164/472 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- EMSY | c.2672C>A p.A891E | Missense Mutation (SNP) | VAF 214/679 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- EVX1 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 177/552 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- F2RL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 74/322 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FNBP1 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 20/552 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- FSIP2 | c.7825G>T p.D2609Y | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GCKR | c.1390C>A p.L464I | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GTF3C3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 17/477 reads (4%) | called by muse, mutect2
- HRNR | c.5725A>T p.R1909W | Missense Mutation (SNP) | VAF 114/1397 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2
- KCP | c.4450C>A p.L1484I (on ENST00000620378; = p.L1608I on NM_001366122.1) | Missense Mutation (SNP) | VAF 475/1210 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF5C | c.440T>A p.L147H | Missense Mutation (SNP) | VAF 173/469 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLF3 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 101/431 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MUC3A | c.4610C>A p.S1537Y | Missense Mutation (SNP) | VAF 193/2024 reads (10%) | SIFT deleterious, low confidence (0.01); called by muse, varscan2
- NDUFAF5 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OR10C1 | c.457G>T p.G153W (on ENST00000622521; = p.G151W on NM_013941.3) | Missense Mutation (SNP) | VAF 21/674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ORC5 | c.833G>T p.W278L | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PALM3 | c.1954G>T p.A652S (on ENST00000340790; = p.A667S on NM_001145028.2) | Missense Mutation (SNP) | VAF 142/379 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLCE1 | c.4992G>T p.E1664D | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PPARGC1B | c.2234C>A p.A745D | Missense Mutation (SNP) | VAF 16/526 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, mutect2
- RAB11FIP3 | c.1115G>T p.R372M | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2
- RIPPLY1 | c.230T>A p.L77* | Nonsense Mutation (SNP) | VAF 151/209 reads (72%) | called by muse, mutect2, varscan2
- RRP9 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 196/549 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RSF1 | c.2407G>T p.G803* | Nonsense Mutation (SNP) | VAF 140/252 reads (56%) | called by muse, mutect2, varscan2
- S1PR4 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCYL1 | c.1386+7G>T | Splice Region (SNP) | VAF 168/461 reads (36%) | called by muse, mutect2, varscan2
- SGCB | c.845G>T p.W282L | Missense Mutation (SNP) | VAF 22/575 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- SIRPG | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 156/568 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by mutect2, varscan2
- SLC7A6 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 176/728 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- SPOCK1 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 142/473 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SZT2 | c.2312C>A p.P771Q | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TBCCD1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 188/461 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TEC | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2
- TET1 | c.2192C>A p.P731Q | Missense Mutation (SNP) | VAF 220/624 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TFAP2A | c.946G>T p.A316S (on ENST00000482890; = p.A308S on NM_001032280.3) | Missense Mutation (SNP) | VAF 25/629 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.047); called by muse, mutect2
- TOR1B | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 150/474 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- URI1 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 23/611 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- VPS4A | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 36/770 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.858); called by muse, mutect2
- ZDBF2 | c.1435C>A p.H479N | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF839 | c.574C>A p.L192M (on ENST00000558850 / NM_001267827.1; = p.L308M on NM_018335.5) | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIS3L | c.2322C>A p.T774= (on ENST00000319212 / NM_001143688.3; = p.T691= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 96/411 reads (23%) | called by muse, varscan2
- HIRIP3 | c.1068C>A p.G356= | Silent (SNP) | VAF 83/324 reads (26%) | called by muse, mutect2, varscan2
- HLA-F | c.696G>A p.A232= | Silent (SNP) | VAF 171/728 reads (23%) | catalogued as rs372957735; called by muse, mutect2, varscan2
- LZTS2 | c.573C>A p.S191= | Silent (SNP) | VAF 131/415 reads (32%) | called by muse, mutect2, varscan2
- NWD1 | c.3615C>A p.S1205= | Silent (SNP) | VAF 76/311 reads (24%) | called by mutect2, varscan2
- OR10G6 | c.885C>A p.V295= | Silent (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- OR2F1 | c.639G>T p.L213= | Silent (SNP) | VAF 167/978 reads (17%) | called by muse, mutect2, varscan2
- PKDREJ | c.4875G>T p.V1625= | Silent (SNP) | VAF 227/561 reads (40%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.330C>A p.G110= | Silent (SNP) | VAF 32/952 reads (3%) | catalogued as COSV101389066; called by muse, mutect2
- SLC35C1 | c.993G>T p.L331= | Silent (SNP) | VAF 15/502 reads (3%) | called by muse, mutect2
- TTBK2 | c.2727C>A p.I909= | Silent (SNP) | VAF 22/624 reads (4%) | called by muse, mutect2
- TUBA3E | c.366C>A p.I122= | Silent (SNP) | VAF 31/1213 reads (3%) | called by muse, mutect2
- ZFHX2 | c.1980C>T p.A660= | Silent (SNP) | VAF 106/476 reads (22%) | called by muse, mutect2, varscan2
- ADHFE1 | c.*61C>A | 3'UTR (SNP) | VAF 45/109 reads (41%) | catalogued as rs1563497856; called by muse, mutect2, varscan2
- AEBP1 | c.1151-82G>T | Intron (SNP) | VAF 15/44 reads (34%) | called by mutect2, varscan2
- AGAP2 | c.2617+18G>T | Intron (SNP) | VAF 74/354 reads (21%) | catalogued as COSV99223195; called by muse, mutect2, varscan2
- ARMC5 | c.1865-71C>A | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- COL11A2 | c.*86C>A | 3'UTR (SNP) | VAF 112/297 reads (38%) | called by muse, mutect2, varscan2
- CXCL5 | c.110-23G>T | Intron (SNP) | VAF 39/385 reads (10%) | catalogued as rs1560549467; called by muse, mutect2
- DNAH8 | c.-207C>A | 5'UTR (SNP) | VAF 18/381 reads (5%) | catalogued as rs1427503743; called by muse, mutect2
- DNHD1 | c.9002+77G>T | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- EIF4B | c.1682+18C>A | Intron (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- HAUS4 | c.709-58C>A | Intron (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- NME1 | c.342-60C>A | Intron (SNP) | VAF 81/263 reads (31%) | called by muse, mutect2, varscan2
- PARP10 | chr8:143991181 del C | 5'Flank (DEL) | VAF 37/141 reads (26%) | catalogued as rs782081768; called by mutect2, pindel, varscan2
- PGA3 | c.219+88G>T | Intron (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- PWWP2B | c.*9C>A | 3'UTR (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- RARG | c.813+56C>A | Intron (SNP) | VAF 106/287 reads (37%) | called by muse, mutect2, varscan2
- SGPL1 | c.*14C>A | 3'UTR (SNP) | VAF 18/483 reads (4%) | called by muse, mutect2
- SRP68 | c.644+69G>T | Intron (SNP) | VAF 80/276 reads (29%) | called by mutect2, varscan2
- TEPSIN | c.49-44G>T | Intron (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- TMEM128 | c.97+20G>T | Intron (SNP) | VAF 114/362 reads (31%) | catalogued as rs774930146; called by muse, mutect2, varscan2
- U2AF2 | c.486+39del | Intron (DEL) | VAF 121/407 reads (30%) | called by mutect2, pindel, varscan2
